Somatic mutation profile of tumor specimen TCGA-E6-A1M0-01A (aliquot TCGA-E6-A1M0-01A-11D-A142-09) from TCGA case TCGA-E6-A1M0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.5 years (20,629 days).
Specimen TCGA-E6-A1M0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 136039d9-dfb0-4ef6-a249-f557b915bcd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E6-A1M0-10A (Blood Derived Normal), aliquot TCGA-E6-A1M0-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0ff8a3-c55d-48f1-b06f-ae044a5036d4

The open-access MAF lists 1,961 somatic variants for this specimen: 1,592 protein-altering or splice-affecting, 321 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,327, Silent 321, Nonsense Mutation 220, Splice Site 27, Intron 27, RNA 11, Splice Region 8, Frame Shift Ins 5, Nonstop Mutation 3, 3'UTR 3, 5'Flank 3, 3'Flank 2.

Variants (750 of 1,961; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- FBXL4 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs754142863, CM159511, CM159512, COSV100014015; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KLHL3 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs863225302, COSV59053989, COSV59054624; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as rs201415996, COSV50395532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs122454127, CM992428, COSV65387529; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs1356008286, COSV57924914; called by muse, mutect2
- AASS | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100741745; called by muse, mutect2
- AATK | c.737G>A p.R246H (on ENST00000326724 / NM_001080395.3; = p.R143H on NM_004920.2) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs771152854, COSV100452730; called by muse, mutect2, varscan2
- ABCA10 | c.3629A>C p.K1210T | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV99288328; called by muse, mutect2, varscan2
- ABCA10 | c.2130A>G p.P710= | Splice Region (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99288330; called by muse, mutect2, varscan2
- ABCA13 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV101329998; called by muse, mutect2, varscan2
- ABCA4 | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs770774738, CM1311030, COSV100933088; called by muse, mutect2, varscan2
- ABCA6 | c.3652G>T p.E1218* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99446217; called by muse, mutect2, varscan2
- ABCA6 | c.1256A>C p.K419T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV99446219; called by muse, varscan2
- ABCA8 | c.3146A>G p.Y1049C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs1253040026, COSV99285398; called by muse, mutect2, varscan2
- ABCA9 | c.3916A>C p.K1306Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100382932; called by muse, mutect2, varscan2
- ABCB4 | c.2963G>A p.G988E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710135; called by muse, mutect2, varscan2
- ABCC12 | c.3901G>T p.D1301Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV60913631; called by muse, mutect2, varscan2
- ABCC2 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755485165, COSV64984961; called by muse, mutect2, varscan2
- ABCC4 | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs370348158; called by muse, varscan2
- ABCC4 | c.3798G>T p.E1266D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100972418; called by muse, varscan2
- ABCC9 | c.4597T>G p.L1533V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99685306; called by muse, mutect2, varscan2
- ABCD3 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100238814, COSV100238987; called by muse, mutect2, varscan2
- AC006059.2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100045390; called by muse, mutect2, varscan2
- AC024598.1 | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100760336; called by muse, mutect2, varscan2
- AC093827.5 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV55744570, COSV99892884; called by muse, mutect2, varscan2
- AC244197.3 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100557916; called by mutect2, varscan2
- ACE | c.3001G>T p.D1001Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99326760; called by muse, mutect2, varscan2
- ACO2 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs371183037; called by muse, mutect2, varscan2
- ACOT9 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs745706448, COSV60537816; called by muse, mutect2, varscan2
- ACP4 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV54517257; called by muse, mutect2, varscan2
- ACSBG1 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV51906355, COSV99357242; called by muse, mutect2, varscan2
- ACSBG1 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs755955040, COSV51905866, COSV99357244; called by muse, mutect2, varscan2
- ACSBG2 | c.1955T>A p.F652Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99397322; called by muse, mutect2, varscan2
- ACSL6 | c.1653A>C p.K551N (on ENST00000379240; = p.K576N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99733266; called by muse, mutect2, varscan2
- ACVR2A | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV54027663, COSV99604303; called by muse, mutect2, varscan2
- ADAD1 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56641122, COSV56642830; called by muse, mutect2, varscan2
- ADAM10 | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99545871; called by muse, mutect2, varscan2
- ADAM23 | c.1116C>A p.F372L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.673); catalogued as COSV100007245; called by muse, mutect2, varscan2
- ADAM23 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1274707603, COSV52211960; called by mutect2, varscan2
- ADAMTS5 | c.2313C>A p.F771L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV53184357; called by muse, mutect2, varscan2
- ADAMTS9 | c.2750G>T p.R917I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99899176; called by muse, mutect2, varscan2
- ADCY2 | c.2547G>T p.E849D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100602448, COSV100604093; called by muse, mutect2
- ADCYAP1R1 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs376384667, COSV58443012, COSV58444209; called by muse, mutect2, varscan2
- ADGRB3 | c.3970G>T p.E1324* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99484507; called by mutect2, varscan2
- ADGRF1 | c.471A>C p.K157N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99347149; called by muse, mutect2, varscan2
- ADGRG2 | c.362T>G p.F121C (on ENST00000379869 / NM_001079858.3; = p.F118C on NM_005756.4) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100492124; called by muse, mutect2, varscan2
- ADGRL2 | c.3280G>T p.E1094* (on ENST00000370717 / NM_001366005.1; = p.E1081* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV54658988; called by muse, mutect2, varscan2
- ADGRV1 | c.4258G>T p.E1420* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV101315728; called by muse, mutect2, varscan2
- ADH1C | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV101565168, COSV101565175, COSV72463588; called by muse, mutect2, varscan2
- AFDN | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV60041076; called by muse, mutect2, varscan2
- AFDN | c.3116C>T p.S1039L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375077108, COSV60038165, COSV60047101; called by muse, mutect2, varscan2
- AFM | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as rs147051358; called by mutect2, varscan2
- AFP | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56925417; called by muse, mutect2, varscan2
- AGBL1 | c.939A>T p.K313N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.462); catalogued as COSV101222631; called by muse, mutect2, varscan2
- AGMO | c.702A>C p.K234N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100693961; called by muse, mutect2, varscan2
- AGPAT4 | c.677A>C p.Y226S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211230; called by muse, mutect2, varscan2
- AHCTF1 | c.6760C>T p.R2254W (on ENST00000366508; = p.R2228W on NM_015446.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs758346249, COSV58248341; called by muse, mutect2, varscan2
- AICDA | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57564058, COSV99984100; called by muse, varscan2
- AIPL1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100006028; called by muse, mutect2, varscan2
- AK9 | c.5052C>A p.F1684L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101413955; called by muse, mutect2, varscan2
- AKAP1 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs189625721, COSV100532789; called by muse, mutect2, varscan2
- AKAP11 | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs576236263, COSV99213747; called by muse, mutect2, varscan2
- AKAP13 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs74597724, COSV100773469, COSV63466051; called by muse, mutect2, varscan2
- AKAP14 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781225508, COSV100538264, COSV57630143, COSV57631417; called by muse, mutect2, varscan2
- AKAP3 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs761284232, COSV99961970; called by muse, mutect2, varscan2
- AKAP9 | c.10550C>T p.S3517L (on ENST00000359028; = p.S3493L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as rs761160065, COSV100662224; called by muse, mutect2, varscan2
- AKAP9 | c.10963G>T p.D3655Y (on ENST00000359028; = p.D3631Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100662225, COSV100662480; called by muse, mutect2, varscan2
- AKR1C1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV101080427; called by muse, mutect2, varscan2
- AL645922.1 | c.1402A>C p.N468H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as COSV100190977; called by muse, mutect2, varscan2
- AL662899.2 | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1374628000, COSV63263683; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALDH9A1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs771178170, COSV61340622; called by muse, mutect2, varscan2
- ALG13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as rs767326994, COSV52636707; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG13 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as COSV52644790; called by muse, mutect2, varscan2
- ALOX12B | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100046894; called by muse, mutect2, varscan2
- AMER1 | c.216C>A p.F72L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV57656423; called by muse, mutect2
- AMFR | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99315790; called by muse, mutect2, varscan2
- ANGEL2 | c.236G>T p.R79I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as COSV100853930; called by muse, mutect2, varscan2
- ANK1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99224743; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANK3 | c.3226G>T p.E1076* (on ENST00000280772 / NM_001320874.2; = p.E210* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99779345; called by muse, mutect2, varscan2
- ANKH | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99414815; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5094G>T p.K1698N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51855942; called by muse, mutect2, varscan2
- ANKRD12 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100041052; called by muse, mutect2, varscan2
- ANKRD12 | c.4106T>G p.F1369C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50820390; called by muse, mutect2, varscan2
- ANKRD13A | c.1181G>T p.R394I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99923905; called by muse, mutect2, varscan2
- ANKRD30A | c.548G>T p.R183I (on ENST00000611781; = p.R127I on NM_052997.2) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64611285; called by muse, mutect2, varscan2
- ANKZF1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV99850425; called by muse, mutect2, varscan2
- ANLN | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99732128; called by muse, mutect2
- AP1B1 | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100434503; called by muse, mutect2, varscan2
- AP5B1 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs745506104, COSV100375979; called by muse, mutect2, varscan2
- APCDD1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs201970588, COSV100789930; called by muse, mutect2, varscan2
- ARAP2 | c.3683T>G p.F1228C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100394391; called by muse, mutect2, varscan2
- ARFGEF2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903939; called by muse, mutect2, varscan2
- ARGLU1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs1467963930, COSV62271553; called by muse, mutect2, varscan2
- ARHGAP11A | c.2075C>A p.S692* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100276731; called by muse, mutect2, varscan2
- ARHGAP11A | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100276741; called by muse, mutect2, varscan2
- ARHGAP27 | c.2048C>T p.S683L (on ENST00000428638 / NM_001282290.1; = p.S342L on NM_199282.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs770853670, COSV100976485; called by muse, mutect2, varscan2
- ARHGAP31 | c.3030C>A p.F1010L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51791065, COSV51801061; called by muse, mutect2, varscan2
- ARHGAP32 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV59856529; called by muse, mutect2, varscan2
- ARHGAP35 | c.2750del p.G917Efs*31 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as COSV68335933; called by mutect2, pindel, varscan2
- ARHGAP4 | c.2619G>T p.Q873H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100509465; called by muse, mutect2, varscan2
- ARHGAP4 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100603975; called by muse, mutect2, varscan2
- ARHGAP44 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99310466; called by muse, mutect2
- ARHGAP5 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs750918486, COSV61540061; called by muse, mutect2, varscan2
- ARHGEF6 | c.923+1G>T p.X308_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99166417; called by muse, mutect2, varscan2
- ARHGEF6 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV51689165, COSV99166766; called by muse, mutect2, varscan2
- ARHGEF7 | c.2323G>T p.E775* (on ENST00000646102 / NM_001354046.1; = p.E559* on NM_003899.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99521344; called by muse, mutect2, varscan2
- ARID4A | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100794147; called by muse, mutect2, varscan2
- ARID5B | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV54414410, COSV54415940; called by muse, mutect2, varscan2
- ARL5A | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.704); catalogued as COSV99706581; called by muse, mutect2, varscan2
- ARMC12 | c.466G>A p.E156K (on ENST00000373866 / NM_001286574.2; = p.E183K on NM_145028.5) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs148096096; called by muse, mutect2, varscan2
- ARMC2 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs757791916, COSV64550311, COSV64551406; called by muse, mutect2, varscan2
- ARMC3 | c.1880G>A p.S627N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV53066660; called by muse, mutect2, varscan2
- ARMCX2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs781812794, COSV57529190; called by muse, mutect2, varscan2
- ARNTL | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1434856001, COSV62985303; called by muse, mutect2, varscan2
- ARPC2 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99826631; called by muse, mutect2, varscan2
- ARRB1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.958); catalogued as rs768596301, COSV63577600; called by muse, mutect2, varscan2
- ARRB1 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100758104; called by muse, mutect2
- ARSJ | c.1665T>G p.Y555* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100192583, COSV100193243; called by muse, mutect2, varscan2
- ARSK | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV101187533; called by muse, mutect2, varscan2
- ARV1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs144095931; called by muse, mutect2, varscan2
- ASB9 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100995451; called by muse, mutect2, varscan2
- ASCC3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138861677, COSV100225520; called by mutect2, varscan2
- ASH1L | c.3981C>A p.F1327L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs762849940, COSV100853310; called by muse, mutect2, varscan2
- ASH2L | c.1673T>G p.F558C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99166956; called by muse, mutect2, varscan2
- ASPM | c.10274C>A p.S3425Y | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV54127420, COSV54137455, COSV99659149; called by muse, mutect2, varscan2
- ASPM | c.6851C>T p.S2284F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs371321801; called by muse, mutect2, varscan2
- ASTE1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs773437504, COSV53909044; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ATAD2B | c.3259T>G p.L1087V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV99477378; called by muse, mutect2, varscan2
- ATF6 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100909114; called by muse, mutect2, varscan2
- ATF7IP | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as COSV99661454; called by muse, mutect2, varscan2
- ATF7IP | c.3302A>G p.Q1101R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99661456; called by muse, mutect2, varscan2
- ATF7IP2 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100202568; called by muse, mutect2, varscan2
- ATG16L1 | c.518T>G p.F173C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100731292; called by muse, mutect2
- ATL1 | c.1110A>C p.K370N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100613000; called by muse, mutect2, varscan2
- ATM | c.8338C>A p.L2780I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53758984; called by muse, mutect2, varscan2
- ATN1 | c.233A>C p.E78A | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV100755743; called by muse, mutect2, varscan2
- ATP10A | c.1828C>A p.L610M | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV100791069; called by muse, mutect2
- ATP11C | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100557700; called by muse, mutect2, varscan2
- ATP13A3 | c.474C>A p.F158L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99756718; called by mutect2, varscan2
- ATP1A3 | c.1507G>A p.D503N (on ENST00000545399 / NM_001256214.2; = p.D490N on NM_152296.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs781976199, COSV100132166; called by muse, mutect2, varscan2
- ATP2A1 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1203742133, COSV100706934; called by muse, mutect2, varscan2
- ATP2B2 | c.2570G>T p.G857V (on ENST00000352432; = p.G823V on NM_001683.5) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659921; called by muse, mutect2, varscan2
- ATP5F1C | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100184298; called by muse, mutect2, varscan2
- ATP6AP1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV100645181; called by muse, mutect2, varscan2
- ATP8B2 | c.2629G>T p.D877Y (on ENST00000672630; = p.D844Y on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100527874, COSV59245914; called by muse, mutect2, varscan2
- ATP8B3 | c.1587G>T p.E529D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.339); catalogued as COSV100034282; called by muse, mutect2, varscan2
- ATP8B4 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV99464702; called by muse, mutect2, varscan2
- ATR | c.6794T>G p.V2265G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100637993; called by muse, mutect2, varscan2
- ATRIP | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100202719; called by muse, mutect2, varscan2
- ATRX | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV100970491, COSV64877609, COSV64882870; called by muse, mutect2, varscan2
- AVEN | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.325); catalogued as COSV100145425, COSV60735758; called by muse, varscan2
- B2M | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV62563143, COSV62564821; called by muse, mutect2, varscan2
- B3GAT2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445262803, COSV57771511; called by muse, mutect2, varscan2
- B3GLCT | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587238; called by muse, mutect2, varscan2
- B4GALNT1 | c.1389C>A p.F463L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100247035; called by muse, mutect2, varscan2
- BACE1 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); catalogued as rs761002162, COSV100474957; called by muse, mutect2, varscan2
- BAZ1A | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV100701117; called by muse, varscan2
- BAZ2B | c.3632C>T p.A1211V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99680918; called by muse, mutect2, varscan2
- BAZ2B | c.1998G>T p.E666D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV100600528; called by muse, mutect2, varscan2
- BBS10 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs553291328, CM111656, COSV99674826; called by muse, mutect2, varscan2
- BCAM | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as rs747031001, COSV54303170, COSV54303356; called by muse, mutect2, varscan2
- BCCIP | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV99532851; called by muse, mutect2, varscan2
- BEND7 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.987); catalogued as COSV100346556; called by muse, mutect2, varscan2
- BFSP1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs774233789, COSV64900837; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2, varscan2
- BIK | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV99330407; called by muse, mutect2, varscan2
- BIRC6 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101428101; called by muse, mutect2, varscan2
- BIRC6 | c.4125G>T p.E1375D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101428102; called by muse, varscan2
- BIRC6 | c.4193G>A p.R1398Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV70197441; called by muse, varscan2
- BMX | c.1371C>A p.F457L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754428384, COSV59590089; called by muse, mutect2, varscan2
- BNC2 | c.2689G>A p.D897N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.34); catalogued as rs756874020, COSV101035740, COSV101036684; called by muse, mutect2, varscan2
- BNIP5 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV101465134; called by muse, mutect2, varscan2
- BOC | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs373840149, COSV99847790; called by muse, mutect2, varscan2
- BOC | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs560351015, COSV99848478; called by muse, mutect2, varscan2
- BRCA1 | c.3781T>G p.L1261V | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD1514817, COSV100523803; called by muse, mutect2, varscan2
- BRCA2 | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66458649; called by muse, mutect2, varscan2
- BRD1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349543; called by muse, mutect2
- BRIP1 | c.1930T>G p.S644A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99369785; called by muse, mutect2, varscan2
- BRIP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs587780225, COSV99369601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.4297C>T p.R1433* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs752494269, COSV60892572; called by muse, mutect2, varscan2
- BRWD3 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100955900, COSV64753583; called by muse, mutect2, varscan2
- BSND | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100987618; called by muse, mutect2, varscan2
- BSPRY | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as COSV100949506; called by muse, mutect2, varscan2
- BTAF1 | c.1734A>T p.E578D | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV99795170; called by muse, mutect2, varscan2
- BTK | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.323); catalogued as CD984238, COSV100437511; called by muse, mutect2, varscan2
- BTN2A1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs546770853, COSV57002135; called by muse, mutect2, varscan2
- BTNL2 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs769178206, COSV100896036; called by muse, mutect2, varscan2
- BUD31 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs769510144, COSV52868654; called by muse, mutect2, varscan2
- C11orf54 | c.904C>T p.R302C (on ENST00000331239; = p.R252C on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371075089, COSV58681451; called by muse, mutect2, varscan2
- C12orf40 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as rs756262005, COSV100209896; called by muse, mutect2, varscan2
- C12orf40 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV100209901; called by muse, mutect2, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C12orf60 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV99966872; called by muse, mutect2, varscan2
- C1GALT1C1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV100485602; called by muse, mutect2, varscan2
- C1R | c.1429C>T p.R477C (on ENST00000536053 / NM_001354346.2; = p.R463C on NM_001733.7) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1169688282, COSV101605612; called by muse, mutect2, varscan2
- C2CD2 | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100298105; called by muse, mutect2, varscan2
- C3 | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs776513727, COSV99836442; called by muse, mutect2, varscan2
- C3orf62 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs780386279, COSV57985348; called by muse, mutect2, varscan2
- C5orf58 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV101406243, COSV69759027; called by muse, mutect2
- C8A | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100776471; called by muse, mutect2, varscan2
- C8orf34 | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327430793, COSV61370989, COSV61395585; called by muse, mutect2, varscan2
- CA12 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as rs774208685, COSV51606665; called by muse, mutect2, varscan2
- CACNA1A | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189054127, COSV64209953; called by muse, mutect2, varscan2
- CACNA1D | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55444993; called by muse, mutect2, varscan2
- CACNA1E | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs770139779, COSV62389864; called by muse, mutect2, varscan2
- CACNA2D1 | c.2557C>A p.L853M (on ENST00000356253 / NM_001366867.1; = p.L841M on NM_000722.4) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100666393, COSV62395702; called by muse, mutect2, varscan2
- CACNA2D3 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV55565916, COSV55574587; called by muse, mutect2, varscan2
- CACNB2 | c.1191G>T p.K397N (on ENST00000324631 / NM_201596.3; = p.K342N on NM_000724.4) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56644089, COSV99993887; called by muse, mutect2, varscan2
- CACNG6 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs1281697505, COSV99403366; called by muse, mutect2, varscan2
- CADPS | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51869263; called by muse, mutect2, varscan2
- CAGE1 | c.2323G>T p.D775Y (on ENST00000512086; = p.D639Y on NM_205864.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV99699557; called by muse, mutect2, varscan2
- CALCOCO2 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV51951113, COSV99363741; called by muse, mutect2
- CAMK1D | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs767783056, COSV66615475; called by muse, mutect2, varscan2
- CAPN6 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV100136810, COSV100136981; called by muse, mutect2, varscan2
- CAPRIN2 | c.2987T>C p.V996A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99195466; called by muse, mutect2, varscan2
- CARMIL1 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV61523370; called by muse, mutect2
- CARNMT1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as rs748737629, COSV100961052; called by mutect2, varscan2
- CASP5 | c.837A>C p.K279N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99507429; called by muse, mutect2, varscan2
- CATSPERE | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100835059; called by muse, mutect2, varscan2
- CBLB | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as rs748390313, COSV51424925; called by muse, mutect2, varscan2
- CBLN1 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54653835, COSV99535626; called by muse, mutect2, varscan2
- CBX1 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV56682110; called by muse, mutect2, varscan2
- CCDC102A | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99264995; called by muse, mutect2, varscan2
- CCDC14 | c.2248T>G p.S750A (on ENST00000488653; = p.S702A on NM_022757.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as COSV100113088; called by muse, mutect2, varscan2
- CCDC178 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100284323; called by muse, mutect2, varscan2
- CCDC186 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.238); catalogued as COSV65159501, COSV65159593; called by muse, mutect2, varscan2
- CCDC62 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53430673; called by muse, mutect2, varscan2
- CCDC66 | c.1055T>G p.I352S (on ENST00000394672 / NM_001353147.1; = p.I318S on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100413847; called by muse, mutect2, varscan2
- CCDC91 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs774693971, COSV60347182; called by muse, mutect2
- CCDC93 | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100098615; called by muse, mutect2, varscan2
- CCL1 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as COSV99861702; called by muse, mutect2, varscan2
- CCN6 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.945); catalogued as rs751421356, COSV100036966; called by muse, mutect2, varscan2
- CCNB3 | c.1918T>C p.S640P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.121); catalogued as COSV52069995, COSV99328813; called by muse, mutect2, varscan2
- CCNL1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as rs748246366, COSV99904457; called by muse, mutect2, varscan2
- CCR3 | c.373A>C p.I125L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV100656435; called by muse, mutect2, varscan2
- CCR4 | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV100447344, COSV58382475; called by muse, mutect2, varscan2
- CCR5 | c.698C>A p.A233D | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99433310; called by muse, mutect2, varscan2
- CD109 | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1400431273, COSV99753193; called by muse, mutect2, varscan2
- CD163L1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58021843; called by muse, mutect2, varscan2
- CD200R1L | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV101236568; called by muse, mutect2, varscan2
- CD207 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101338543; called by muse, mutect2, varscan2
- CD300C | c.159C>G p.N53K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.185); catalogued as COSV100423235; called by muse, mutect2, varscan2
- CD55 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as CM076088, COSV58576670; called by muse, mutect2, varscan2
- CD79A | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99701972; called by muse, mutect2, varscan2
- CD86 | c.364C>T p.R122C (on ENST00000330540 / NM_175862.5; = p.R116C on NM_006889.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as rs770052627, COSV100053903; called by muse, mutect2, varscan2
- CD96 | c.1146T>G p.I382M (on ENST00000283285 / NM_198196.3; = p.I366M on NM_005816.5) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51917932; called by muse, mutect2, varscan2
- CDC40 | c.1298T>G p.F433C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100309228; called by muse, mutect2, varscan2
- CDC42 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV59661832; called by muse, mutect2, varscan2
- CDCA2 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100398815; called by muse, mutect2, varscan2
- CDH18 | c.822G>C p.Q274H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV99933601; called by muse, mutect2, varscan2
- CDH9 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50251836, COSV50254045; called by muse, mutect2, varscan2
- CDK16 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.634); catalogued as rs752502574, COSV99331590; called by muse, mutect2, varscan2
- CDK5RAP1 | c.928G>A p.E310K (on ENST00000357886 / NM_001365728.1; = p.E296K on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100212013, COSV104411314; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3229T>G p.S1077A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100575308; called by muse, mutect2, varscan2
- CDKL5 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101184217; called by muse, mutect2, varscan2
- CDYL2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs145890469; called by muse, mutect2, varscan2
- CDYL2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756720865, COSV101629580, COSV73654363; called by muse, mutect2, varscan2
- CEACAM19 | c.705T>C p.A235= | Splice Region (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100715433; called by muse, mutect2, varscan2
- CEACAM21 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as COSV99494432; called by muse, mutect2, varscan2
- CELSR2 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193826222, COSV99603537; called by muse, mutect2, varscan2
- CEMIP2 | c.3208C>T p.R1070* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV65484514; called by muse, mutect2, varscan2
- CENPE | c.2466C>A p.F822L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54392225, COSV99477540; called by muse, mutect2, varscan2
- CENPE | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54382015; called by muse, varscan2
- CENPJ | c.3533G>A p.R1178Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs773273237, COSV55039649; called by muse, mutect2, varscan2
- CEP112 | c.1328G>T p.R443I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.66); catalogued as COSV67141204; called by muse, mutect2, varscan2
- CEP128 | c.1210-1G>T p.X404_splice | Splice Site (SNP) | VAF 15/27 reads (56%) | catalogued as COSV55373515; called by muse, mutect2, varscan2
- CEP162 | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100002615; called by muse, mutect2, varscan2
- CEP19 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56361484; called by muse, mutect2, varscan2
- CEP250 | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs755541063, COSV61170171; called by muse, mutect2, varscan2
- CEP350 | c.7985C>A p.S2662Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100854462; called by muse, mutect2, varscan2
- CEP41 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56220360; called by muse, mutect2, varscan2
- CEP43 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs868230727, COSV100835591; called by muse, mutect2, varscan2
- CEP78 | c.1602C>A p.F534L (on ENST00000424347 / NM_001349840.2; = p.F535L on NM_032171.3) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99450207; called by muse, mutect2, varscan2
- CFAP52 | c.1491G>T p.Q497H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100235008; called by muse, mutect2, varscan2
- CFAP61 | c.3001G>T p.E1001* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as rs752168009, COSV55629511, COSV55637932, COSV99844252; called by muse, mutect2, varscan2
- CFAP61 | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs189288996, COSV55635115; called by muse, mutect2, varscan2
- CFAP65 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377355595; called by muse, mutect2, varscan2
- CFAP70 | c.2485C>A p.L829I | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV60282100; called by muse, mutect2, varscan2
- CFAP70 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV100160413; called by muse, mutect2, varscan2
- CFHR2 | c.669G>T p.W223C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100804297, COSV66380667; called by muse, mutect2, varscan2
- CFHR5 | c.575T>G p.F192C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99888170, COSV99888374; called by muse, mutect2, varscan2
- CHCHD6 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs1178786637, COSV99335994; called by muse, mutect2, varscan2
- CHD2 | c.1720-1G>T p.X574_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV101245043; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, mutect2, varscan2
- CHD4 | c.101-1G>T p.X34_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100537639, COSV58895388; called by muse, mutect2, varscan2
- CHD8 | c.3207C>A p.F1069L (on ENST00000646647 / NM_001170629.2; = p.F790L on NM_020920.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67870447; called by muse, mutect2, varscan2
- CHD9 | c.996G>T p.L332F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101272048; called by muse, mutect2, varscan2
- CHD9 | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99529014; called by muse, mutect2
- CHL1 | c.3223G>T p.D1075Y (on ENST00000397491 / NM_001253387.1; = p.D1091Y on NM_006614.4) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99850721; called by muse, varscan2
- CHODL | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99517524; called by muse, mutect2, varscan2
- CHRM3 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs200936697, COSV99698004; called by muse, mutect2, varscan2
- CHRM5 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101271899; called by muse, mutect2, varscan2
- CHST10 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.795); catalogued as COSV99958842; called by muse, mutect2, varscan2
- CHST4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs752235839, COSV100632841; called by muse, mutect2, varscan2
- CLCN1 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV58368742; called by muse, mutect2, varscan2
- CLDN18 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV104386110, COSV51736103; called by muse, varscan2
- CLDN4 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99936402; called by muse, mutect2, varscan2
- CLDN6 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs766294662, COSV58509385; called by muse, mutect2, varscan2
- CLINT1 | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV51623219; called by muse, mutect2
- CLN5 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101080270; called by muse, mutect2, varscan2
- CLPS | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99463674; called by muse, mutect2, varscan2
- CLTC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99291998; called by muse, mutect2, varscan2
- CMIP | c.735C>A p.F245L (on ENST00000537098 / NM_198390.2; = p.F151L on NM_030629.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV101220879; called by muse, mutect2, varscan2
- CMYA5 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374313124, COSV71409406; called by muse, varscan2
- CMYA5 | c.730T>G p.F244V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs763385104, COSV101483976; called by muse, varscan2
- CMYA5 | c.3778C>A p.L1260I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1193096769, COSV71404537; called by muse, mutect2, varscan2
- CNDP2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100159058; called by muse, mutect2, varscan2
- CNOT6L | c.400G>T p.G134C (on ENST00000504123 / NM_001286790.2; = p.G129C on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99361618; called by muse, mutect2
- CNTFR | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV100667501; called by muse, mutect2, varscan2
- CNTN1 | c.2472G>T p.E824D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV100751197; called by muse, mutect2, varscan2
- CNTNAP1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV52853506, COSV99226242; called by muse, mutect2, varscan2
- CNTNAP2 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV62162831, COSV62229133; called by muse, mutect2
- CNTNAP3 | c.3689C>T p.A1230V | Missense Mutation (SNP) | VAF 144/631 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs71236525, COSV52664388; called by muse, mutect2, varscan2
- CNTNAP5 | c.2993T>C p.V998A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV70490733; called by muse, mutect2, varscan2
- CNTNAP5 | c.3378C>A p.F1126L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101443323, COSV101443597; called by muse, mutect2, varscan2
- COL11A1 | c.5127T>G p.N1709K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100615913, COSV62187637; called by muse, mutect2, varscan2
- COL4A1 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011060; called by muse, mutect2, varscan2
- COL5A1 | c.2213T>C p.I738T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100879756; called by muse, mutect2, varscan2
- COL5A3 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99318525; called by muse, mutect2, varscan2
- COL6A1 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs767395722, COSV100720094; called by muse, mutect2, varscan2
- COL6A3 | c.7147A>G p.I2383V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as COSV99797353; called by muse, mutect2, varscan2
- COL6A6 | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs370896099; called by muse, mutect2, varscan2
- COL9A3 | c.2031G>T p.E677D | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV99415709; called by muse, mutect2, varscan2
- COPA | c.3115C>A p.L1039I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.111); catalogued as COSV99615211; called by muse, mutect2, varscan2
- COPB1 | c.2788C>A p.R930S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51448599, COSV99999434; called by muse, mutect2, varscan2
- COPB2 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs745747191, COSV100169028; called by muse, mutect2, varscan2
- CPA6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs375296440, COSV52725616; called by muse, mutect2, varscan2
- CPED1 | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV100120440; called by muse, mutect2, varscan2
- CPLX4 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV55312747, COSV55313119, COSV55313627; called by muse, mutect2, varscan2
- CPOX | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99939074; called by muse, mutect2, varscan2
- CPQ | c.924T>G p.F308L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV99611362; called by muse, mutect2, varscan2
- CPS1 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV99242659; called by muse, mutect2, varscan2
- CPS1 | c.3523G>T p.E1175* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99242661, COSV99244451; called by muse, mutect2, varscan2
- CPSF2 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100102714, COSV100102912; called by muse, mutect2
- CPSF6 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99879175; called by muse, mutect2, varscan2
- CR2 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100889585; called by muse, mutect2, varscan2
- CREBL2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99963606; called by muse, mutect2, varscan2
- CRK | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100315588; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1507T>C p.S503P | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174763; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59974096, COSV59983029; called by muse, mutect2, varscan2
- CSMD1 | c.6843T>G p.D2281E (on ENST00000520002; = p.D2280E on NM_033225.6) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100146336; called by muse, mutect2, varscan2
- CSMD3 | c.10743T>A p.V3581= (on ENST00000297405 / NM_001363185.1; = p.V3412= on NM_052900.3) | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99830684; called by muse, mutect2
- CSMD3 | c.9380G>A p.R3127Q (on ENST00000297405 / NM_001363185.1; = p.R2958Q on NM_052900.3) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.888); catalogued as rs752773200, COSV52165293, COSV52249136; called by muse, mutect2, varscan2
- CSMD3 | c.8833G>T p.E2945* (on ENST00000297405 / NM_001363185.1; = p.E2776* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99830688; called by muse, mutect2, varscan2
- CSMD3 | c.8534C>A p.P2845H (on ENST00000297405 / NM_001363185.1; = p.P2676H on NM_052900.3) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99830690; called by muse, mutect2, varscan2
- CSNK1G3 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs868190621, COSV62056061; called by muse, mutect2, varscan2
- CSRNP1 | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99826788; called by muse, mutect2, varscan2
- CSRNP1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759995863, COSV99826653; called by muse, mutect2, varscan2
- CSRP2 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV60702141; called by muse, mutect2, varscan2
- CT55 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99358837; called by muse, mutect2, varscan2
- CTAGE1 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV66943438; called by muse, mutect2, varscan2
- CTAGE6 | c.617C>A p.A206D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV101417831; called by mutect2, varscan2
- CTNNB1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62705582; called by muse, mutect2, varscan2
- CTPS1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs1176322200, COSV101009312; called by muse, mutect2
- CUBN | c.10246G>A p.D3416N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1249826348, COSV100912405; called by muse, mutect2, varscan2
- CUX1 | c.1440C>G p.F480L (on ENST00000437600 / NM_181500.4; = p.F482L on NM_001913.5) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.066); catalogued as COSV99475256; called by muse, mutect2, varscan2
- CWC25 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs760543725; called by muse, mutect2, varscan2
- CXCR6 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.284); catalogued as COSV99945459; called by muse, mutect2, varscan2
- CYBB | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as CD050130, COSV101059727; called by muse, mutect2, varscan2
- CYLC1 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs768170993, COSV61410911; called by muse, mutect2, varscan2
- CYP11A1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as rs755186597, CM1210478, COSV99165954; called by muse, mutect2, varscan2
- CYP27C1 | c.642A>C p.L214F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100079773; called by muse, mutect2, varscan2
- CYP2C8 | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs758378725, COSV64876295, COSV64878505; called by muse, mutect2, varscan2
- CYP7B1 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.122); catalogued as COSV100041272; called by muse, mutect2, varscan2
- CYTH3 | c.1181G>A p.R394Q (on ENST00000396741; = p.R393Q on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs780996917, COSV60364287; called by muse, mutect2, varscan2
- CYTH3 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV63440607; called by muse, mutect2, varscan2
- DARS2 | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV53408776; called by muse, mutect2, varscan2
- DCLK3 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759600419, COSV101374115, COSV69364041; called by muse, mutect2, varscan2
- DCLRE1A | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100800304; called by mutect2, varscan2
- DCSTAMP | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV99886384; called by muse, mutect2, varscan2
- DCTN1 | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100720904; called by muse, mutect2, varscan2
- DDB1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1487985200, COSV57103466; called by muse, mutect2, varscan2
- DDX20 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs773108633, COSV63831036; called by muse, mutect2, varscan2
- DDX5 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV56751143; called by muse, mutect2, varscan2
- DDX50 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65291862; called by muse, mutect2
- DDX53 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60068610; called by muse, mutect2, varscan2
- DEFB104A | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.017); catalogued as COSV100055375; called by muse, mutect2, varscan2
- DENND5A | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs761947253, COSV60235755; called by muse, mutect2, varscan2
- DEUP1 | c.1631T>C p.F544S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as COSV99976992; called by muse, mutect2, varscan2
- DGKB | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV99338228; called by muse, mutect2
- DHX34 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100169442; called by muse, mutect2
- DIP2B | c.2991G>T p.W997C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99998265; called by muse, mutect2, varscan2
- DIPK1A | c.270A>C p.K90N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.261); catalogued as COSV100942054; called by muse, mutect2, varscan2
- DIPK2A | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100237188; called by muse, mutect2, varscan2
- DIS3L | c.554T>G p.F185C (on ENST00000319212 / NM_001143688.3; = p.F102C on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100055098; called by muse, mutect2, varscan2
- DLC1 | c.3883A>C p.N1295H (on ENST00000276297 / NM_001348081.2; = p.N858H on NM_006094.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52306797, COSV99362354; called by mutect2, varscan2
- DLGAP5 | c.577A>C p.K193Q | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV99903816; called by muse, mutect2, varscan2
- DMD | c.10172G>A p.R3391Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1423537877, COSV58896676; called by muse, mutect2, varscan2
- DMD | c.9137G>A p.G3046D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100626714; called by muse, mutect2, varscan2
- DMD | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV99921199; called by muse, mutect2, varscan2
- DMXL2 | c.2714C>A p.S905Y | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99196186; called by muse, mutect2, varscan2
- DNAH10 | c.4717A>C p.K1573Q (on ENST00000409039; = p.K1512Q on NM_207437.3) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV101292154; called by muse, mutect2, varscan2
- DNAH5 | c.11966A>C p.K3989T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV99447919; called by muse, mutect2, varscan2
- DNAH5 | c.5962G>T p.E1988* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV54215341; called by muse, mutect2, varscan2
- DNAH7 | c.4481C>A p.S1494Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414643; called by muse, mutect2, varscan2
- DNAH8 | c.12676G>A p.E4226K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV100544295; called by muse, mutect2, varscan2
- DNAI1 | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99646731; called by muse, mutect2, varscan2
- DNAI4 | c.1383A>G p.I461M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as COSV100925266; called by muse, mutect2, varscan2
- DNAJC19 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV62801801; called by muse, mutect2, varscan2
- DNER | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486878125, COSV100518774; called by muse, mutect2
- DOCK10 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV104383925; called by muse, mutect2
- DOCK11 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99353476; called by muse, mutect2, varscan2
- DOCK11 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99353477; called by muse, mutect2, varscan2
- DOCK11 | c.2049T>C p.C683= | Splice Region (SNP) | VAF 27/71 reads (38%) | catalogued as rs1027040279, COSV99353479; called by muse, mutect2, varscan2
- DPP4 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV62108060; called by muse, mutect2, varscan2
- DPP9 | c.821G>A p.R274Q (on ENST00000598800; = p.R303Q on NM_139159.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.274); catalogued as rs367692337, COSV99506104; called by muse, mutect2, varscan2
- DSC3 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs779053546, COSV100844420; called by muse, mutect2, varscan2
- DSCAML1 | c.6035C>A p.S2012Y (on ENST00000321322; = p.S1952Y on NM_020693.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV100355517, COSV58386186; called by muse, mutect2, varscan2
- DSG2 | c.2556G>T p.E852D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV99853007; called by muse, mutect2, varscan2
- DSPP | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.036); catalogued as COSV99217032; called by mutect2, varscan2
- DST | c.15401A>C p.D5134A (on ENST00000361203 / NM_001374722.1; = p.D2722A on NM_015548.5) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.681); catalogued as COSV99753972; called by muse, mutect2, varscan2
- DST | c.7359G>T p.E2453D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55027756, COSV99753975; called by muse, mutect2, varscan2
- DUOX2 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as rs564054264, COSV100545823; called by muse, mutect2, varscan2
- DYM | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as rs202085847, COSV53982925, COSV99494463; called by mutect2, varscan2
- DYNC1I1 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV100268037; called by muse, mutect2, varscan2
- DYNC2H1 | c.9327G>T p.L3109F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518159; called by muse, mutect2, varscan2
- DYNC2H1 | c.12716C>A p.S4239Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100518160; called by muse, mutect2, varscan2
- E2F3 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100685901; called by muse, mutect2, varscan2
- ECHDC1 | c.282A>C p.E94D (on ENST00000531967 / NM_001139510.1; = p.E88D on NM_018479.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100541661; called by muse, mutect2, varscan2
- ECHS1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745362960, COSV63907156; called by muse, mutect2, varscan2
- EED | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54555680, COSV54559053; called by muse, mutect2, varscan2
- EFCAB1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs201706002, COSV100030541, COSV50617834; called by muse, varscan2
- EFCAB7 | c.1877C>A p.S626Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs149784056, COSV100937634; called by muse, mutect2, varscan2
- EFHB | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV55546270, COSV99859396; called by muse, mutect2, varscan2
- EGF | c.1390T>G p.F464V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV99490722; called by muse, mutect2, varscan2
- EHBP1 | c.627A>C p.K209N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99860541; called by muse, mutect2, varscan2
- EHBP1L1 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100499803; called by muse, mutect2, varscan2
- EIF2B1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs962257544, COSV99967503; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767295081, COSV100348981; called by muse, mutect2, varscan2
- ELF2 | c.344G>T p.R115I (on ENST00000379550 / NM_001331036.2; = p.R55I on NM_006874.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV99642766; called by muse, mutect2, varscan2
- ELK1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs766008788, COSV55952051; called by muse, mutect2, varscan2
- ELMOD2 | c.227A>C p.D76A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV100062836; called by muse, mutect2, varscan2
- EMD | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as CD078077, COSV63962464; called by muse, mutect2, varscan2
- ENGASE | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as rs547678422, COSV56135272; called by muse, mutect2, varscan2
- ENKUR | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV58632435; called by muse, mutect2, varscan2
- ENTHD1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100288641; called by muse, mutect2, varscan2
- EP300 | c.3685G>T p.E1229* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV54344399; called by muse, mutect2, varscan2
- EP300 | c.6787C>T p.R2263* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54337914; called by muse, mutect2, varscan2
- EPG5 | c.5500C>A p.L1834I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99956968; called by muse, mutect2, varscan2
- EPHA5 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV56630579, COSV56683300; called by muse, mutect2, varscan2
- EPHA8 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51285870; called by muse, mutect2, varscan2
- EPHX2 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs1563341872, COSV66845545; called by muse, mutect2, varscan2
- EPN2 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs960054704, COSV100127518; called by muse, mutect2, varscan2
- EPS8L3 | c.1741C>T p.R581W (on ENST00000361965 / NM_133181.4; = p.R551W on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs554030593, COSV62608734; called by muse, mutect2, varscan2
- ERBB3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs755757062, COSV99916450; called by muse, mutect2, varscan2
- ERCC6L | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750289131, COSV57819326; called by muse, mutect2, varscan2
- ERN2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99891172; called by muse, mutect2
- ERO1A | c.873T>G p.I291M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs749646868, COSV101193605; called by muse, mutect2, varscan2
- ERVFRD-1 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100977371; called by muse, mutect2, varscan2
- ESCO2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767123113, COSV59414087; called by muse, varscan2
- ETFDH | c.1546T>G p.F516V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306764; called by muse, mutect2, varscan2
- EVPL | c.2268G>T p.K756N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV100044306; called by muse, mutect2, varscan2
- EXOC1 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV62122246; called by muse, mutect2, varscan2
- EXOSC7 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs751989948, COSV99651931; called by muse, mutect2, varscan2
- EYS | c.1565C>A p.S522Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1383137389, COSV100676208; called by muse, mutect2, varscan2
- EYS | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100676209; called by muse, mutect2, varscan2
- EZHIP | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV57957185; called by muse, mutect2, varscan2
- EZHIP | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100539606; called by muse, mutect2, varscan2
- F8 | c.3899G>T p.G1300V | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100811415; called by muse, mutect2, varscan2
- F8 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM010837, CM083643, COSV100811417; called by muse, mutect2, varscan2
- F9 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as COSV99496480; called by muse, mutect2, varscan2
- FABP1 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV99860847, COSV99860895; called by muse, mutect2, varscan2
- FABP2 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV56789284; called by muse, mutect2, varscan2
- FAM135B | c.2728G>T p.D910Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV52713267, COSV52739007; called by muse, varscan2
- FAM13A | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs747994413, COSV99983290; called by muse, mutect2, varscan2
- FAM13B | c.768A>C p.E256D | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as COSV99221220; called by muse, mutect2, varscan2
- FAM167A | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780501946, COSV99034062, COSV99453132; called by muse, mutect2, varscan2
- FAM169A | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV100769086; called by muse, mutect2, varscan2
- FAM171B | c.1732A>C p.N578H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100488453; called by muse, mutect2, varscan2
- FAM172A | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67942054; called by muse, mutect2, varscan2
- FAM47A | c.1878G>T p.R626S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs756248152, COSV100649812; called by muse, mutect2, varscan2
- FAM47A | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV60494534; called by muse, mutect2, varscan2
- FAM47B | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1480429154, COSV100264234, COSV100264550; called by muse, varscan2
- FAM47C | c.2588T>C p.V863A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.159); catalogued as COSV100792433; called by muse, mutect2, varscan2
- FAM78A | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1325823077, COSV55992065; called by muse, mutect2
- FAM78B | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100597490, COSV57975204; called by muse, mutect2, varscan2
- FAM9B | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV59119004; called by muse, mutect2, varscan2
- FAM9B | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV100510946; called by muse, mutect2, varscan2
- FANCD2 | c.3035T>G p.I1012S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99810966; called by muse, mutect2, varscan2
- FAT1 | c.13360G>A p.E4454K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs367799188; called by muse, mutect2, varscan2
- FAT2 | c.9994G>T p.E3332* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV55829655; called by muse, mutect2, varscan2
- FAT2 | c.7894G>T p.D2632Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV55822298; called by muse, mutect2, varscan2
- FAT2 | c.7759G>T p.A2587S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99942345; called by muse, mutect2, varscan2
- FAT3 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99964437; called by muse, mutect2, varscan2
- FAT3 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); catalogued as rs374699170, COSV53088142; called by muse, mutect2, varscan2
- FAT3 | c.9599C>T p.S3200L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.476); catalogued as rs376790690; called by muse, mutect2, varscan2
- FAT4 | c.9046G>T p.G3016* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100628099; called by muse, mutect2, varscan2
- FBLN5 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as rs1052990296, COSV99969487; called by muse, mutect2, varscan2
- FBN1 | c.5072G>T p.R1691I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100354495; called by muse, mutect2, varscan2
- FBN1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as rs542798262, COSV57308921, COSV57320554, COSV57322251; called by muse, mutect2, varscan2
- FBXL4 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs149860873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs369589187; called by muse, mutect2, varscan2
- FBXO3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs754213126, COSV55766012; called by muse, mutect2, varscan2
- FBXO3 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV99682051; called by muse, mutect2, varscan2
- FBXW11 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1384571474, COSV99440177; called by muse, mutect2, varscan2
- FCN3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs745599639, COSV99585314; called by muse, mutect2, varscan2
- FER | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99812305; called by muse, mutect2, varscan2
- FGA | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs766472109, COSV100120295; called by muse, mutect2, varscan2
- FGD6 | c.585T>G p.I195M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.055); catalogued as COSV100676492; called by muse, mutect2, varscan2
- FHL1 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100600736; called by muse, mutect2, varscan2
- FIG4 | c.956C>A p.S319Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100019468; called by muse, mutect2, varscan2
- FILIP1 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99384409, COSV99384908; called by muse, mutect2, varscan2
- FKBP14 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV56107252, COSV56107379; called by muse, mutect2, varscan2
- FLG | c.11905C>A p.Q3969K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.088); catalogued as COSV64251594; called by muse, mutect2, varscan2
- FLNC | c.3581C>T p.S1194L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs773481064, COSV57950001, COSV57954920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54078310, COSV99610314; called by muse, mutect2, varscan2
- FOLH1 | c.1889-1G>T p.X630_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99923015; called by muse, mutect2, varscan2
- FOXF1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV52285411, COSV52286010; called by muse, mutect2, varscan2
- FOXO1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65426118; called by muse, mutect2, varscan2
- FPR1 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100494017; called by muse, mutect2, varscan2
- FREM1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs772215299, COSV101085775, COSV66518648; called by muse, mutect2, varscan2
- FRMD7 | c.1584G>T p.M528I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100048848; called by muse, mutect2
- FRMPD1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs979040535, COSV100899520, COSV100899551; called by muse, mutect2, varscan2
- FRMPD1 | c.3726G>T p.R1242S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV100899522; called by muse, mutect2, varscan2
- FRMPD2 | c.1514A>C p.E505A | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100563720; called by muse, mutect2, varscan2
- FRMPD4 | c.3647C>A p.S1216Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101042600; called by muse, mutect2, varscan2
- FUT9 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56144793, COSV56145570; called by muse, mutect2, varscan2
- FZD8 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101020208; called by muse, mutect2, varscan2
- G2E3 | c.238-1G>T p.X80_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52839416; called by muse, mutect2, varscan2
- GAB1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201202756, COSV53757363; called by muse, mutect2, varscan2
- GABARAPL1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV56770461, COSV99845443; called by muse, mutect2, varscan2
- GABRB3 | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.649); catalogued as COSV100159188; called by muse, mutect2, varscan2
- GABRR3 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs376960773; called by muse, mutect2, varscan2
- GAD1 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1369644885, COSV100713961, COSV60154151; called by muse, mutect2, varscan2
- GAD2 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99392996; called by muse, mutect2, varscan2
- GAL3ST4 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV100385432; called by muse, mutect2, varscan2
- GALNT15 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs767157320, COSV100327507; called by muse, mutect2, varscan2
- GALNT3 | c.1801T>C p.F601L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1201348122, COSV101204899; called by muse, mutect2, varscan2
- GALNT3 | c.408A>C p.E136D | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs756804696, COSV101204900; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by muse, mutect2, varscan2
- GARNL3 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs148770742; called by muse, mutect2, varscan2
- GAS2L2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs769306206; called by muse, mutect2, varscan2
- GAS7 | c.876C>A p.F292L (on ENST00000432992 / NM_201433.2; = p.F152L on NM_003644.3) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1251176426, COSV100095127; called by muse, mutect2, varscan2
- GBF1 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV100890409; called by muse, mutect2, varscan2
- GC | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56739904, COSV99909589; called by muse, mutect2, varscan2
- GCC1 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99133683; called by muse, mutect2, varscan2
- GCNT4 | c.692T>G p.F231C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100466349; called by muse, mutect2, varscan2
- GDF3 | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100325219; called by muse, mutect2, varscan2
- GDI1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV50130712; called by muse, mutect2, varscan2
- GDPD2 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100978594; called by muse, mutect2, varscan2
- GFM2 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99714205; called by muse, mutect2, varscan2
- GFM2 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99714208; called by muse, mutect2, varscan2
- GFPT2 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283136533, COSV99517541; called by muse, mutect2, varscan2
- GIGYF1 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV99308636; called by muse, mutect2, varscan2
- GK | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV66734180; called by muse, mutect2
- GLS2 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100358305; called by muse, mutect2, varscan2
- GNPDA2 | c.236G>T p.R79I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs1438281145, COSV54946385; called by muse, mutect2, varscan2
- GOLGA4 | c.6677G>A p.R2226H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs773081235, COSV100728796, COSV62710878; called by muse, mutect2, varscan2
- GOLPH3L | c.315+1G>A p.X105_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99653718; called by muse, mutect2, varscan2
- GOLT1B | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57552973; called by muse, mutect2, varscan2
- GOT1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as rs375319064; called by muse, mutect2, varscan2
- GPA33 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs747670451, COSV63300386, COSV63300512; called by muse, mutect2, varscan2
- GPBP1 | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV99302673; called by muse, mutect2, varscan2
- GPBP1 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99302676; called by muse, mutect2
- GPBP1L1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99322137; called by muse, mutect2, varscan2
- GPC3 | c.1293-1G>A p.X431_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100892915; called by muse, mutect2, varscan2
- GPC4 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.476); catalogued as rs962591498, COSV63697027; called by muse, mutect2, varscan2
- GPI | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as rs547475819, COSV99874956; called by muse, mutect2, varscan2
- GPKOW | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99332574; called by muse, mutect2, varscan2
- GPNMB | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99326419; called by muse, mutect2, varscan2
- GPR101 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV53239789, COSV53240383; called by muse, mutect2, varscan2
- GPR155 | c.2171G>T p.R724I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV55038240; called by muse, mutect2, varscan2
- GPR18 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs367795735; called by muse, mutect2, varscan2
- GPR6 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51572250; called by muse, mutect2, varscan2
- GPR63 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as rs541468268, COSV57742726; called by muse, mutect2
- GPR87 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.235); catalogued as rs764492925, COSV53463046; called by muse, mutect2, varscan2
- GPRC5C | c.1285G>A p.E429K (on ENST00000652232; = p.E384K on NM_018653.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as rs548471843, COSV61235162; called by muse, mutect2, varscan2
- GPX5 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV69079216, COSV69079830; called by muse, mutect2
- GRAMD1A | c.584G>A p.W195* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100526096; called by muse, mutect2, varscan2
- GRAP2 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as rs781122629, COSV100702928; called by muse, mutect2, varscan2
- GRHL1 | c.1146C>A p.F382L | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257700; called by muse, mutect2
- GRIK2 | c.864A>C p.Q288H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100024843; called by muse, mutect2, varscan2
- GRK3 | c.1035G>T p.K345N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as COSV60794599; called by muse, mutect2, varscan2
- GRK4 | c.327C>A p.F109L (on ENST00000398052 / NM_182982.3; = p.F77L on NM_005307.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.409); catalogued as COSV61667953; called by muse, mutect2
- GRK4 | c.665G>T p.R222I (on ENST00000398052 / NM_182982.3; = p.R190I on NM_005307.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100583959; called by muse, mutect2, varscan2
- GRM7 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs771695147, COSV63142162; called by muse, mutect2, varscan2
- GSK3A | c.472-1G>T p.X158_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as COSV104382610, COSV99725186; called by muse, mutect2, varscan2
- GSK3A | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55899756; called by muse, mutect2, varscan2
- GSK3B | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as COSV99954485; called by muse, mutect2, varscan2
- GSX2 | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482540; called by muse, mutect2, varscan2
- GTDC1 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99600018; called by muse, mutect2, varscan2
- GTF3C1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1340597679, COSV62240781; called by muse, mutect2, varscan2
- GUCY2C | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV53790466, COSV99663481; called by muse, mutect2, varscan2
- GUCY2F | c.1948C>A p.L650I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99484782; called by muse, mutect2, varscan2
- H3-4 | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs772146691, COSV100797377; called by muse, mutect2, varscan2
- HABP4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs375474752; called by muse, mutect2, varscan2
- HACL1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV100337186; called by muse, mutect2, varscan2
- HAO2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs760870079, COSV58038381; called by muse, mutect2, varscan2
- HAPLN1 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57151590, COSV99164780; called by muse, mutect2, varscan2
- HAT1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99907881; called by muse, mutect2, varscan2
- HAUS7 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV100444064; called by muse, mutect2, varscan2
- HCK | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757866724, COSV99393939, COSV99394128; called by muse, mutect2, varscan2
- HDAC6 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as rs782125114, COSV61928314; called by muse, mutect2, varscan2
- HDAC8 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101002358; called by muse, mutect2, varscan2
- HDX | c.1741-1G>T p.X581_splice | Splice Site (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99947043; called by muse, mutect2, varscan2
- HEATR4 | c.3015C>A p.F1005L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV58569754; called by muse, mutect2, varscan2
- HEATR4 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100620291; called by muse, mutect2
- HEATR5A | c.2813C>A p.S938Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1166130925, COSV66338738, COSV66339766; called by muse, mutect2, varscan2
- HEATR5B | c.2067T>G p.F689L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99248897; called by muse, mutect2
- HECA | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757761408, COSV100866180; called by muse, mutect2, varscan2
- HECTD4 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as COSV101106878, COSV66391214; called by muse, mutect2, varscan2
- HERC6 | c.342A>C p.E114D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV99910505; called by muse, mutect2, varscan2
- HEY2 | c.363C>A p.F121L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs750867284, COSV100856352; called by muse, mutect2, varscan2
- HFM1 | c.3433C>A p.H1145N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54023650, COSV99645804; called by muse, mutect2, varscan2
- HGF | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99736408; called by muse, mutect2, varscan2
- HHLA2 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV100755328; called by muse, mutect2, varscan2
- HIPK1 | c.878G>T p.R293I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101060296; called by muse, mutect2, varscan2
- HIPK3 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs773029433, COSV57562873; called by muse, mutect2, varscan2
- HM13 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100159399; called by muse, mutect2, varscan2
- HM13 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100159402; called by muse, mutect2, varscan2
- HMBS | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs756417575, COSV53830091; called by muse, mutect2, varscan2
- HMGB3 | c.291-1G>A p.X97_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100308480; called by muse, mutect2, varscan2
- HMMR | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV100700981; called by muse, mutect2
- HNRNPH2 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100347002; called by muse, mutect2, varscan2
- HOXD13 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs767313108, COSV66832302; called by muse, mutect2, varscan2
- HPRT1 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV53776491; called by muse, mutect2, varscan2
- HPSE2 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs373432908; called by muse, mutect2, varscan2
- HSD11B1 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV54826304; called by muse, mutect2, varscan2
- HSPA4 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100507608; called by muse, mutect2, varscan2
- HSPB8 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs774767632, COSV99931198; called by muse, mutect2, varscan2
- HSPH1 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100184829; called by muse, mutect2, varscan2
- IFRD1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771235895, COSV99133713; called by muse, mutect2, varscan2
- IFT80 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100424606, COSV58447537; called by mutect2, varscan2
- IGBP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV60555912; called by muse, mutect2, varscan2
- IGF2R | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV63630941; called by muse, mutect2, varscan2
- IGLV3-27 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as rs542783344; called by muse, mutect2, varscan2
- IGSF10 | c.7301T>G p.I2434S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177555; called by muse, mutect2, varscan2
- IGSF21 | c.1034A>C p.K345T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV99244383; called by muse, mutect2, varscan2
- IGSF9B | c.3637A>G p.T1213A | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100317360; called by muse, mutect2, varscan2
- IL10RA | c.1556C>A p.P519H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as COSV99922967; called by muse, mutect2, varscan2
- IL1RAPL1 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100146577; called by muse, mutect2, varscan2
- IL1RAPL1 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV56281070; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1637C>A p.S546Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61144737; called by muse, mutect2, varscan2
- IL9R | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV99729587; called by muse, mutect2, varscan2
- IMPG1 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs765332581, COSV63113102; called by muse, mutect2
- ING2 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV100180404; called by muse, mutect2, varscan2
- INSL4 | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 19/38 reads (50%) | catalogued as COSV99497107; called by muse, mutect2, varscan2
- INSRR | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs201715497, COSV63871157; called by muse, mutect2, varscan2
- INTS3 | c.1935G>T p.E645D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as COSV100015834, COSV59681244; called by muse, mutect2, varscan2
- INTS4 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101417161; called by muse, mutect2, varscan2
- INTS6L | c.1400A>C p.K467T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV66084020; called by muse, mutect2, varscan2
- IPO7 | c.2689G>T p.E897* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101121810; called by muse, mutect2, varscan2
- IQCH | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100245628; called by muse, mutect2, varscan2
- IQCH | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100245629; called by muse, mutect2, varscan2
- IRAK1 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100888974; called by muse, mutect2, varscan2
- IRS4 | c.2932C>A p.L978I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100929408; called by muse, mutect2, varscan2
- ITCH | c.2025G>T p.K675N (on ENST00000262650 / NM_001257137.3; = p.K634N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV99392272, COSV99393471; called by muse, mutect2, varscan2
- ITGA6 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV99905309; called by muse, mutect2, varscan2
- ITGAM | c.3160T>A p.F1054I (on ENST00000648685 / NM_001145808.2; = p.F1053I on NM_000632.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99792164; called by muse, mutect2, varscan2
- ITIH6 | c.3110G>A p.G1037E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs1257458821, COSV99513121; called by muse, mutect2, varscan2
- ITIH6 | c.3098C>A p.P1033H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV99513123; called by muse, mutect2, varscan2
- ITIH6 | c.1074C>T p.G358= | Splice Region (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99513003; called by muse, mutect2, varscan2
- JAM2 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.24); catalogued as COSV100468102; called by muse, mutect2, varscan2
- JAM3 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as COSV100138002; called by muse, mutect2, varscan2
- JHY | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs150680420; called by muse, mutect2, varscan2
- JOSD1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs866931747, COSV53265433; called by muse, mutect2, varscan2
- KANSL1 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99294338; called by muse, mutect2, varscan2
- KCND2 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100474886; called by muse, mutect2, varscan2
- KCNF1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99705653; called by muse, mutect2, varscan2
- KCNH6 | c.1514C>G p.A505G | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100120934, COSV59006500; called by muse, mutect2, varscan2
- KCNJ6 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899582; called by muse, mutect2, varscan2
- KCNN2 | c.907A>G p.K303E (on ENST00000264773; = p.K515E on NM_021614.4) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99299373; called by muse, mutect2, varscan2
- KCNT2 | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54079224; called by muse, mutect2, varscan2
- KCNT2 | c.544-1G>T p.X182_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV54089152, COSV99652764; called by muse, mutect2, varscan2
- KDR | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99817264; called by muse, mutect2, varscan2
- KIAA0100 | c.2720G>T p.R907I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101197272; called by mutect2, varscan2
- KIAA0232 | c.3651A>C p.E1217D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV100300603, COSV56923912; called by muse, mutect2, varscan2
- KIAA1210 | c.2930C>A p.S977Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV101274029, COSV68176417; called by muse, mutect2, varscan2
- KIAA1210 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs1400388889, COSV68176148, COSV68176331; called by muse, mutect2, varscan2
- KIAA1210 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV101274048; called by muse, mutect2, varscan2
- KIAA1328 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs536436186, COSV54448669; called by muse, mutect2, varscan2
- KIAA2026 | c.5875C>A p.P1959T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs768297602, COSV101198950; called by muse, mutect2, varscan2
- KIF13A | c.5201C>A p.S1734Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs750676792, COSV99435198; called by muse, mutect2, varscan2
- KIF14 | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as rs756824898, COSV66262504; called by muse, mutect2
- KIF1B | c.1886A>G p.N629S (on ENST00000377086 / NM_001365952.1; = p.N583S on NM_015074.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV99822991; called by muse, mutect2, varscan2
- KIF20B | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201280490, COSV53317475; called by muse, mutect2, varscan2
- KIF20B | c.2880G>T p.K960N (on ENST00000371728 / NM_001284259.2; = p.K920N on NM_016195.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV53310715; called by muse, mutect2, varscan2
- KIF27 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99926890; called by muse, mutect2
- KIF2A | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242069125, COSV66945853; called by muse, mutect2, varscan2
- KIF3A | c.1482G>T p.E494D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV66414007; called by muse, mutect2, varscan2
- KIF5B | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56650829; called by muse, mutect2, varscan2
- KIT | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853820; called by mutect2, varscan2
- KLHL13 | c.1391G>T p.R464I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV99451443; called by muse, mutect2
- KLHL4 | c.1761G>T p.M587I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100909395, COSV64143751; called by muse, mutect2, varscan2
- KLHL7 | c.720G>T p.K240N (on ENST00000339077 / NM_001031710.3; = p.K192N on NM_018846.5) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as COSV59164803; called by muse, mutect2, varscan2
- KLHL9 | c.1417T>G p.W473G | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757052; called by muse, mutect2
- KMT2A | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100628507; called by muse, mutect2, varscan2
- KMT2D | c.16273G>A p.E5425K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM146878, COSV56454472; called by muse, mutect2, varscan2
- KMT2D | c.9797T>C p.L3266P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV56485310, COSV99979802; called by mutect2, varscan2
- KNDC1 | c.4600C>A p.L1534M | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58842091; called by muse, mutect2, varscan2
- KRT20 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs201355464, COSV99391348; called by muse, mutect2, varscan2
- KRT27 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as rs376178361; called by muse, mutect2, varscan2
- KRT34 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs139913573, COSV101222525; called by muse, mutect2, varscan2
- KRT74 | c.731T>G p.F244C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99977473; called by muse, mutect2
- KSR1 | c.2021C>T p.S674L (on ENST00000644974 / NM_001367810.1; = p.S559L on NM_014238.2) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1421756754, COSV52029184, COSV99260697; called by muse, mutect2, varscan2
- KTN1 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100783244; called by muse, mutect2, varscan2
- L3MBTL4 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201734535, COSV99528338; called by muse, mutect2, varscan2
- LACTB | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318554352, COSV99978905; called by muse, mutect2, varscan2
- LACTB | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486880436, COSV56055347; called by muse, mutect2
- LAMA2 | c.8918C>T p.T2973M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs145842163, COSV101370335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB1 | c.1800C>A p.F600L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55964482; called by muse, mutect2, varscan2
- LANCL1 | c.617T>G p.M206R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99286238; called by muse, mutect2, varscan2
- LATS1 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs568586257, COSV53590864; called by muse, mutect2, varscan2
- LDHAL6A | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV99323843; called by muse, mutect2, varscan2
- LGALS8 | c.596G>A p.R199Q (on ENST00000341872; = p.R241Q on NM_006499.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs765494178, COSV99436395; called by muse, mutect2, varscan2
- LGI2 | c.656-1G>T p.X219_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101180802, COSV66122813; called by muse, mutect2
- LILRB4 | c.1253G>T p.S418I (on ENST00000391733 / NM_001278428.3; = p.S417I on NM_001278426.3) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.187); catalogued as COSV99553685; called by muse, mutect2, varscan2
- LIPC | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs777672660, COSV54427182; called by muse, mutect2, varscan2
- LIPI | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100753592; called by muse, mutect2, varscan2
- LIX1L | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV63417122; called by mutect2, varscan2
- LNX2 | c.1887C>A p.F629L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV100310648; called by muse, mutect2, varscan2
- LPCAT1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52036023; called by muse, mutect2, varscan2
- LRFN5 | c.1934G>T p.R645I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99983192; called by muse, mutect2, varscan2
- LRP12 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs779021302, COSV99407504; called by muse, mutect2, varscan2
- LRP2 | c.12955C>T p.R4319* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as rs868444553, COSV55549994; called by muse, mutect2, varscan2
- LRRC17 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99978330; called by muse, mutect2, varscan2
- LRRC2 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56126105, COSV99947331; called by muse, mutect2, varscan2
- LRRC28 | c.1048T>C p.F350L | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV100113475; called by muse, mutect2, varscan2
- LRRC4 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV50815895; called by muse, mutect2, varscan2
- LRRC7 | c.292G>T p.E98* (on ENST00000651989 / NM_001370785.2; = p.E65* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99225769; called by muse, mutect2, varscan2
- LRRC71 | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV61656495; called by muse, mutect2, varscan2
- LRRIQ1 | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV101277708; called by muse, mutect2, varscan2
- LSM1 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV100258347; called by muse, mutect2
- LTV1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs201919461; called by muse, mutect2, varscan2
- LUC7L2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs761762656, COSV54925953; called by muse, mutect2, varscan2
- LY75-CD302 | c.5030_5032del p.C1677del | In Frame Del (DEL) | VAF 9/21 reads (43%) | catalogued as rs1283108779; called by pindel, varscan2
- LY96 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV99514371; called by muse, mutect2
- LYZL4 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as rs750501330, COSV99821193; called by muse, mutect2, varscan2
- LZTR1 | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV99301571; called by muse, mutect2
- MACF1 | c.18313C>A p.L6105I (on ENST00000372915; = p.L4150I on NM_012090.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as rs770987231; called by muse, mutect2, varscan2
- MAEL | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs768269478, COSV63304489; called by muse, mutect2, varscan2
- MAEL | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs751586017, COSV63305529; called by muse, mutect2, varscan2
- MAGEA11 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV60754450; called by muse, mutect2, varscan2
- MAGEA4 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1225342823, COSV52341486; called by muse, mutect2, varscan2
- MAGEC3 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100025178; called by muse, mutect2, varscan2
- MAGEC3 | c.1473G>T p.K491N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV100025179; called by muse, mutect2, varscan2
- MAGED2 | c.1014A>C p.E338D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99514491; called by muse, mutect2, varscan2
- MAL | c.96C>A p.I32= | Splice Region (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100015698; called by muse, mutect2, varscan2
1,211 further variants in this file (842 protein-altering or splice-affecting, 321 silent, 48 other) are not listed here.
